Surgical pathology report (de-identified scan), TCGA case TCGA-NA-A4QX, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Duke University, specimen TCGA-NA-A4QX-01A (Primary Tumor).

[page 1 of 2]
ICD- O-3
Carcinosarcoma, NOS 8980/3
Site: Uterus, NOS C55.9
Coded AUS 1/18/13

Surg Path

CLINICAL HISTORY:

Malignant neoplasm corpus uteri 182.0. Cervical mass, high grade sarcoma.

GROSS EXAMINATION:

A. "Right pelvic sidewall (AF1)", received fresh for frozen section and placed in formalin at [REDACTED] are two equally sized (2.5 x 0.7 x 0.3 cm fragments of tan fibroadipose tissue, that are entirely frozen as AF1). The frozen section remnant is submitted in lens paper in block A1.

B. "Uterus, cervix, right and left ovaries and tubes". Received fresh and placed in formalin at [REDACTED] is a 241 gram, 7.5 x 6.5 x 5 cm uterus and attached right adnexa. The ectocervix is 8 cm in diameter and the os is dilated to 6 cm, and there is a 7 x 6.5 x 5 cm necrotic mass protruding through the os with a pedunculated base adherent to the inferior endometrium. The sectioned mass has a white, rubbery, fibrous cord, surrounded by a rim of red, gray-brown hemorrhage and necrosis. The mass is then 1.2 cm into a 3.2 cm thick trabeculated myometrium. Additionally, there is a 0.8 x 0.6 x 0.4 cm pedunculated polyp on the anterior endometrium and a 1.4 x 1.3 x 0.5 cm pedunculated polyp in the anterior lower uterine segment. The endometrial cavity is 3 x 3 cm and demonstrates a 0.1 cm flattened endometrium with a 2 cm thick trabeculated myometrium that discloses a 1 cm in diameter white whorled nodule in the posterior portion. The serosal surface is tan, smooth, glistening and grossly unremarkable.

The attached right adnexa (approximately 6 grams) has a 6.5 cm long, 0.5 cm in diameter fimbriated fallopian tube, and a 2.5 x 2 x 1 cm white, gray, bosselated ovary. The sectioned gross ovary and tube are grossly unremarkable.

Received in the same container is a 6 gram, 6.8 cm long, 0.5 cm in diameter left fallopian tube with an attached 1.9 x 1.9 x 0.8 cm left ovary that upon sectioning reveals a 1 x 0.8 x 0.8 cm white, cystic nodule in the parenchyma, but is otherwise grossly unremarkable.

BLOCK SUMMARY:

- B1- anterior endo exocervix
- B2- posterior endo ectocervix
- B3-6- full thickness anterior endomyometrium, bisected (base of mass, at deepest invasion)
- B7-9- mass
- B10- anterior polyp
- B11- anterior full thickness endomyometrium (uninvolved), bisected
- B12- posterior full thickness endomyometrium (uninvolved)
- B13- right ovary and tube
- B14- left ovary and tube

C. "Omentum", received fresh and placed in formalin at [REDACTED] is a 20.2 x 18.3 x 3.5 cm aggregate of omental fat that is sectioned to reveal multiple areas of firm white, fibrous nodules, ranging in size from 0.7 x 0.6 x 0.5 cm to 5 x 4 x 3.5 cm (C1-2).

D. "Left pelvic sidewall", received fresh and placed in formalin at [REDACTED] is a 2.5 x 1.3 x 0.7 cm fragment of fibrofatty tissue, that is bisected and submitted entirely in block D1.

INTRA OPERATIVE CONSULTATION:

[page 2 of 2]
A. "Right pelvic sidewall":
AF1 (toto)-malignant [REDACTED]

MICROSCOPIC EXAMINATION:
Microscopic examination is performed.

PATHOLOGIC STAGE:
PROCEDURE: HYSTERECTOMY & OOPHORECTOMY, AND BIOPSIES

PATHOLOGIC STAGE: pT3b (FIGO 2008) pNX PMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

B. UTERUS, 241 GM
TUMOR

TUMOR SITE: ENDOMETRIAL
HISTOLOGIC TYPE: CARCINOSARCOMA
FIGO GRADE: N.A.
TUMOR SIZE: 7 x 6.5 x 5 CM.
MAX DEPTH OF INVASION: 1.2 CM, IN A 3.2 CM THICK WALL.
LYMPHATIC/VASCULAR INVASION: NEGATIVE.
MITOSES: 1 /10 HPFs
ENDOMETRIUM, NON-NEOPLASTIC:
QUIESCENT
POLYP
REMAINING MYOMETRIUM: LEIOMYOMA, SMALL
CERVIX: 1 MM TUMOR METASTASIS IN THE DEEP WALL JUST AT JUNCTION OF
LOWER UTERINE SEGMENT AND CERVIX.
SEROA: NO PATHOLOGIC DIAGNOSIS.
SPECIMEN MARGINS: NOT INVOLVED

THE FOLLOWING SPECIMENS DISCLOSE METASTATIC/IMPLANTED TUMOR

- A. PELVIC SIDEWALL
- B. OVARIES, BILATERAL, MICROSCOPIC
- C. OMENTUM, EXTENSIVE
- D. LEFT PELVIC SIDEWALL

NOTE: The tumor has various histologies. The metastases are largely epithelial with a marked stromal response including a desmoplastic stromal response. The tumor in the uterus varies from more epithelial cancer to areas resembling a clear cell cancer, to some areas resembling an alveolar soft part sarcoma, and extensive areas of an undifferentiated sarcoma with few mitoses.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

CI ADDENDUM 1:

Please see [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file c099daff-ba70-42e1-88b2-892166ec6e5b (TCGA-NA-A4QX.9E2960D7-2884-429F-9EE7-997FA498FA11.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).